Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JS, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JS-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Incidental finding of a large right sided adrenal tumor. Stitch on anterior surface.

PROCEDURE: SPGD

1. "Right adrenal and right kidney"

Received in formalin in a large container is a nephrectomy specimen with attached adrenal mass overall measuring 16.5 x 10 x 6 cm. The superior adrenal mass is partially encapsulated with a purple-gray possible fascia on the anterior aspect. It is roughened with fibroadipose tissue on the posterior aspect. A 3.2 x 2.2 cm gray-white plaque is identified on the posterior aspect of the adrenal to kidney. The specimen has an untrimmed weight of 640 grams. Posterior aspect is inked black and the anterior is inked blue. The tumor is partially adhered to the renal artery. It does not appear to invade the lumen. No lymph nodes are identified at the hilum. The specimen is bivalved. The adrenal mass is 7.2 x 5.5 x 4.7 cm. It is irregular, ill-defined focal areas partially encapsulated with a bright yellow-orange tissue. The cut surface is a lobular tan hemorrhagic tissue with focal areas of necrosis that occupy approximately 15%. The central portion is remarkable for a 4.2 x 3.3 cm cystic area lined with a gray-white granular tissue. It is devoid of contents. The adrenal mass compresses and extends to the superior pole of the kidney. A scant amount of possible normal adrenal gland is identified, 4.2 x 1.1 x 0.2 cm. The adrenal mass has a trimmed weight of 140 grams. Upon sectioning other areas are partially surrounded with a rim of yellow-orange possibly normal adrenal gland. Upon sectioning the area of the aforementioned plaque and area of necrotic yellow-red possible tumor tissue extends to this region. The 190 gram trimmed kidney is 11 x 7 x 4.5 cm. The cut surface is a pink-tan kidney parenchyma with a well-defined corticomedullary junction. No abnormalities are noted. No lesions are identified. Photographs have been taken.

1A-D. Tumor to anterior capsule.

1E-F. Tumor to posterior plaque.

1G-H. Tumor to possible normal adrenal gland.

1I-J. Tumor to superior pole of kidney.

1K. Vascular and ureter margins.

1L-M. Normal kidney renal sinus upper pole.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA
V4

Tumor Size: 7.2 x 5.5 x 4.7 cm.

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site: Adrenal Gland, cortex

C74.0

9/20/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: _____

PAGE #: 2

BIRTHDATE: _____

PAT TYPE: _____

SEX: F

ADM DATE: _____

OPER DATE: _____

Tumor Weight: 140 grams.

Capsular Invasion: No.

Vascular Invasion: No.

Surgical Margins: Negative.

Necrosis: Yes, 15%.

Mitotic Rate: (Mits per 50 high power fields): 35/50 HPF.

Grade: High grade.

Lymph nodes status: N.A.

Extra-adrenal extension: No.

Stage: T2 NX MX

Immunohistochemistry Results: N.A.

PROCEDURE: SPDY

1. Right adrenal gland, resection: High grade adrenocortical carcinoma (7.2 cm), margins negative. See template for details.

Right kidney, resection: Unremarkable renal cortex and medulla without diagnostic abnormality. Negative for neoplasm.

_____ the signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 2c5be4f9-2910-4608-8807-49177f9caded (TCGA-OR-A5JS.B6E65697-5AE8-45B4-9FAA-D25B8F57988F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).